CPTAC case C3L-03635 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/66cdc2a1-48f9-41df-92a3-c64dbb685019

Demographics
Sex at birth: male; Year of birth: 1954; Vital status: Dead; Days to death: 854 days (2.3 years); Year of death: 2020; Cause of death: Cancer Related.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Tail of pancreas; Age at diagnosis: 63.7 years (23,274 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 854 days (2.3 years); Progression or recurrence: yes; Days to last follow up: 854 days (2.3 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.2 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 313 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 789 days (2.2 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 565 days (1.5 years); Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 854 days (2.3 years); Disease response: Progressive Disease; Karnofsky performance status: 40; ECOG performance status: 3.

Other clinical attributes
- Weight: 73.2 kg; Height: 168 cm; BMI: 25.94.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03635-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 28 days; Initial weight: 72.7 mg; Time between excision and freezing: 46 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03635-21: Section location: Tail; Percent tumor nuclei: 20; Percent necrosis: 0.
- Sample C3L-03635-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 28 days; Initial weight: 107.8 mg; Time between excision and freezing: 46 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03635-22: Section location: Tail; Percent tumor nuclei: 20; Percent necrosis: 0.
- Sample C3L-03635-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 28 days; Method of sample procurement: Blood Draw.
